Somatic mutation profile of tumor specimen TCGA-O2-A52V-01A (aliquot TCGA-O2-A52V-01A-31D-A25L-08) from TCGA case TCGA-O2-A52V, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage II; Age at diagnosis: 75.2 years (27,449 days).
Specimen TCGA-O2-A52V-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c164dd82-7399-4c92-ad66-534a1be7010c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-O2-A52V-10A (Blood Derived Normal), aliquot TCGA-O2-A52V-10A-01D-A25L-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6d9efaec-0bc0-4a3f-8b0e-03962d42adcf

The open-access MAF lists 259 somatic variants for this specimen: 187 protein-altering or splice-affecting, 65 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 166, Silent 65, Nonsense Mutation 10, Frame Shift Del 4, Splice Site 3, 5'Flank 3, Intron 2, Nonstop Mutation 1, In Frame Del 1, Frame Shift Ins 1, 3'UTR 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.527G>A p.C176Y | Missense Mutation (SNP) | VAF 10/50 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs786202962, COSV52660760, COSV52661329, COSV52678029; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AASDH | c.890G>T p.G297V | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99221403; called by muse, mutect2, varscan2
- AC005833.1 | c.964G>T p.V322L | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as COSV99362898; called by muse, mutect2, varscan2
- ACAN | c.6404C>A p.A2135E | Missense Mutation (SNP) | VAF 37/111 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV100718317; called by muse, mutect2, varscan2
- ADAM32 | c.1063G>T p.G355C | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101165416; called by muse, mutect2, varscan2
- ADCY2 | c.1814C>T p.T605I | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.133); catalogued as rs1319668885, COSV100603063; called by muse, mutect2, varscan2
- ADD1 | c.644G>C p.G215A | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.173); catalogued as COSV99296578; called by muse, mutect2, varscan2
- ADGRV1 | c.10276G>A p.A3426T | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV101316094; called by muse, mutect2
- ADGRV1 | c.10866A>C p.K3622N | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.054); catalogued as COSV101316095; called by muse, mutect2, varscan2
- AGO2 | c.2317C>T p.R773C | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs777477236, COSV55047682; called by muse, mutect2, varscan2
- AKAP14 | c.295G>A p.V99I | Missense Mutation (SNP) | VAF 27/131 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.065); catalogued as rs1211723259, COSV57631271; called by muse, mutect2, varscan2
- AL121899.2 | c.428C>A p.S143Y | Missense Mutation (SNP) | VAF 33/210 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV67350861; called by muse, mutect2, varscan2
- ANKAR | c.1264A>T p.K422* | Nonsense Mutation (SNP) | VAF 8/48 reads (17%) | catalogued as COSV99854341; called by muse, mutect2, varscan2
- AQR | c.2707G>T p.A903S | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as rs1566982414, COSV99333990, COSV99334090; called by muse, mutect2, varscan2
- ARL4D | c.412G>T p.D138Y | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100186410; called by muse, mutect2, varscan2
- ARSF | c.1231G>T p.A411S | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.393); catalogued as COSV100839410, COSV100839527; called by muse, varscan2
- ASAP2 | c.1638G>T p.K546N | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.746); catalogued as COSV99856325; called by muse, mutect2, varscan2
- ASTL | c.989C>T p.A330V | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.084); catalogued as rs570403802, COSV60905315; called by muse, mutect2, varscan2
- ATP2A2 | c.2282G>T p.R761L | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as CM101465, COSV100428684; called by muse, mutect2, varscan2
- BHMT | c.425T>C p.L142P | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.106); catalogued as COSV99165441; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.2959G>T p.V987L | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.003); catalogued as COSV100863795; called by muse, mutect2, varscan2
- CA3 | c.140G>T p.W47L | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.037); catalogued as COSV99570725; called by muse, mutect2, varscan2
- CACNB4 | c.1398G>T p.R466S | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.058); catalogued as COSV99138451; called by muse, mutect2, varscan2
- CAMK2A | c.1120G>A p.D374N (on ENST00000348628 / NM_171825.2; = p.D385N on NM_015981.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.183); catalogued as COSV62245757, COSV62246315; called by muse, mutect2, varscan2
- CAMK2A | c.1119C>A p.C373* (on ENST00000348628 / NM_171825.2; = p.C384* on NM_015981.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 5/30 reads (17%) | catalogued as COSV100652048; called by muse, mutect2, varscan2
- CASK | c.1894C>A p.P632T | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100587332; called by muse, mutect2, varscan2
- CCDC106 | c.575C>T p.T192I | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100454286; called by muse, mutect2
- CD163L1 | c.4183G>T p.V1395F | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV100550177; called by muse, mutect2
- CD2AP | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV100830459, COSV63762865; called by muse, mutect2, varscan2
- CD2AP | c.172A>G p.K58E | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.156); catalogued as COSV100830462; called by muse, mutect2, varscan2
- CD4 | c.935T>A p.V312E | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99163798; called by muse, mutect2, varscan2
- CDH10 | c.1250C>A p.P417H | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.478); catalogued as COSV100051848; called by muse, mutect2
- CDR1 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 34/124 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV100983421; called by muse, mutect2, varscan2
- CEP170 | c.2791C>T p.P931S | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100317071, COSV100317249; called by muse, mutect2, varscan2
- CFAP47 | c.107G>A p.R36K | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99935209; called by muse, mutect2, varscan2
- CFAP69 | c.934A>G p.I312V | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.107); catalogued as rs772196992, COSV100290193; called by muse, mutect2, varscan2
- CHD7 | c.176C>G p.T59S | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.007); catalogued as rs548706525, COSV101418275; ClinVar: likely benign; called by muse, varscan2
- CIAO2A | c.455T>C p.V152A | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV100256627; called by muse, mutect2, varscan2
- CLEC2D | c.325G>T p.D109Y | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.389); catalogued as COSV99325029; called by muse, mutect2, varscan2
- CLEC4D | c.546T>G p.C182W | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100223038; called by muse, mutect2, varscan2
- CLSTN2 | c.1495G>T p.A499S | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101515796; called by muse, mutect2, varscan2
- CNGA3 | c.1091C>A p.T364N | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99736150; called by muse, mutect2, varscan2
- CRACD | c.2026C>A p.L676M | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV51733948; called by muse, mutect2, varscan2
- CTNNA3 | c.1855G>T p.D619Y | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101050048; called by muse, mutect2, varscan2
- CUBN | c.1741G>A p.V581I | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0.028); catalogued as COSV100912850; called by muse, mutect2, varscan2
- CUL4B | c.2614G>A p.E872K | Missense Mutation (SNP) | VAF 48/301 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100340691; called by muse, mutect2, varscan2
- CYSTM1 | c.78G>C p.M26I | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as COSV99944998; called by muse, mutect2, varscan2
- DCAF8L1 | c.1760C>A p.S587Y | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.503); catalogued as COSV101491474; called by muse, mutect2, varscan2
- DCP1B | c.1009C>A p.P337T | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.116); catalogued as COSV99767590; called by muse, mutect2, varscan2
- DENND4A | c.2753G>A p.R918K | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV101475361; called by muse, mutect2
- DGKD | c.2836G>C p.E946Q (on ENST00000264057 / NM_152879.3; = p.E902Q on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.626); catalogued as COSV99896555; called by muse, mutect2, varscan2
- DIDO1 | c.3532G>C p.E1178Q | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV99826138; called by muse, mutect2, varscan2
- DMKN | c.911C>A p.S304Y | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.563); catalogued as COSV100303677, COSV60086498; called by muse, mutect2, varscan2
- DMRTA1 | c.1049G>T p.R350L | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as COSV100364790; called by muse, mutect2, varscan2
- DNAJC10 | c.2252A>G p.Y751C | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.98); catalogued as rs763908727, COSV99899356; called by muse, mutect2, varscan2
- DPY19L2 | c.2101G>T p.E701* | Nonsense Mutation (SNP) | VAF 10/78 reads (13%) | catalogued as COSV100193569; called by muse, mutect2, varscan2
- DRD2 | c.733A>G p.T245A | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT tolerated (0.54); PolyPhen benign (0.009); catalogued as COSV100669773; called by muse, mutect2
- DYSF | c.2182C>T p.H728Y | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.217); catalogued as rs749143065, COSV99063655, COSV99247822; called by muse, mutect2, varscan2
- ELAVL2 | c.77C>A p.S26* | Nonsense Mutation (SNP) | VAF 28/137 reads (20%) | catalogued as COSV99806413; called by muse, mutect2, varscan2
- ELF4 | c.619A>T p.S207C | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as COSV100257412; called by muse, mutect2, varscan2
- ENPEP | c.2169A>T p.Q723H | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs150207444; called by muse, mutect2, varscan2
- EXT1 | c.912G>T p.W304C | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM099157, COSV100984026; called by muse, mutect2, varscan2
- F2R | c.493G>T p.G165C | Missense Mutation (SNP) | VAF 36/198 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100058491; called by muse, mutect2, varscan2
- FAM133A | c.690C>A p.H230Q | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.147); catalogued as COSV100220431; called by muse, mutect2, varscan2
- FBXW7 | c.175G>T p.V59F | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.011); catalogued as COSV99903304; called by muse, mutect2, varscan2
- FCSK | c.739G>T p.A247S | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.68); catalogued as COSV99850954; called by muse, mutect2, varscan2
- FIG4 | c.310G>T p.G104C | Missense Mutation (SNP) | VAF 25/143 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1466735496, COSV100019777; called by muse, mutect2, varscan2
- FLAD1 | c.107G>T p.R36L | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV99422617; called by muse, mutect2, varscan2
- FLT3 | c.2053+1G>T p.X685_splice | Splice Site (SNP) | VAF 7/29 reads (24%) | catalogued as COSV99609023; called by muse, mutect2, varscan2
- FOXC2 | c.646G>T p.E216* | Nonsense Mutation (SNP) | VAF 3/15 reads (20%) | catalogued as COSV100234295, COSV57444394; called by muse, mutect2
- FUBP1 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.584); catalogued as COSV99628979; called by muse, varscan2
- FUT6 | c.35C>T p.S12L | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as rs377238448; called by muse, mutect2, varscan2
- GALNT13 | c.1021G>T p.V341F | Missense Mutation (SNP) | VAF 27/157 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as COSV67222922; called by muse, mutect2, varscan2
- GBP7 | c.467C>T p.S156L | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.606); catalogued as rs754826455, COSV99643186; called by muse, mutect2
- GIMAP5 | c.843G>C p.L281F | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT tolerated (0.71); PolyPhen benign (0.343); catalogued as COSV100500258; called by muse, mutect2
- GPATCH1 | c.415C>T p.P139S | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.209); catalogued as rs144397243; called by muse, mutect2, varscan2
- GPRASP2 | c.143C>A p.A48E | Missense Mutation (SNP) | VAF 22/184 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.111); catalogued as COSV100176786; called by muse, mutect2, varscan2
- GRIA3 | c.1469G>T p.W490L | Missense Mutation (SNP) | VAF 28/146 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV99990534; called by muse, mutect2, varscan2
- GUCY2F | c.1912C>G p.Q638E | Missense Mutation (SNP) | VAF 25/130 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99485142; called by muse, mutect2, varscan2
- GZMH | c.589G>C p.G197R | Missense Mutation (SNP) | VAF 25/194 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as COSV99361956, COSV99362033; called by muse, mutect2, varscan2
- HEPH | c.250G>T p.D84Y (on ENST00000343002; = p.D138Y on NM_138737.5) | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); catalogued as COSV100295002, COSV57959524; called by muse, mutect2, varscan2
- HRH1 | c.1335C>G p.C445W | Missense Mutation (SNP) | VAF 43/218 reads (20%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.75); catalogued as rs778860317, COSV101229070; called by muse, mutect2, varscan2
- HUWE1 | c.7115G>A p.S2372N | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.075); catalogued as COSV99472743; called by muse, mutect2, varscan2
- JPH3 | c.933C>G p.Y311* | Nonsense Mutation (SNP) | VAF 12/54 reads (22%) | catalogued as COSV99413516; called by muse, mutect2, varscan2
- KCNH6 | c.433T>C p.S145P | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.062); catalogued as COSV100121107; called by muse, mutect2, varscan2
- KDM5C | c.3673C>T p.P1225S | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV100949248; called by muse, mutect2
- KIF4A | c.2563G>C p.E855Q | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.756); catalogued as COSV100979548; called by muse, mutect2, varscan2
- KNG1 | c.421G>A p.D141N | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV99405626; called by muse, mutect2
- KNSTRN | c.17C>A p.A6D | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs964368911; called by muse, mutect2, varscan2
- LDLRAD4 | c.107A>G p.N36S | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.996); catalogued as COSV100762306; called by muse, mutect2
- LPAR2 | c.67G>C p.E23Q | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.48); PolyPhen benign (0.005); catalogued as COSV99179323; called by muse, mutect2, varscan2
- LRRC15 | c.908A>C p.N303T | Missense Mutation (SNP) | VAF 33/103 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100752753; called by muse, mutect2, varscan2
- LYST | c.363A>T p.K121N | Missense Mutation (SNP) | VAF 25/132 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.51); catalogued as COSV101089696; called by muse, mutect2, varscan2
- MAGEC1 | c.308C>G p.P103R | Missense Mutation (SNP) | VAF 29/126 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.804); catalogued as COSV99595849; called by muse, mutect2, varscan2
- MAGEE1 | c.1617C>A p.H539Q | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100819419; called by muse, mutect2, varscan2
- MAGEE1 | c.1618C>A p.L540M | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.998); catalogued as COSV100819420; called by muse, mutect2, varscan2
- MAGI3 | c.2498C>A p.P833H | Missense Mutation (SNP) | VAF 49/210 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56827568; called by muse, mutect2, varscan2
- MAPK4 | c.340C>T p.R114C | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.025); catalogued as rs186595195, COSV68541012; called by muse, mutect2, varscan2
- MCF2L2 | c.1280T>C p.L427S | Missense Mutation (SNP) | VAF 15/161 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100192805; called by muse, mutect2
- MOXD1 | c.351C>A p.H117Q | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV100381641, COSV100382105; called by muse, mutect2, varscan2
- MYF5 | c.49G>A p.D17N | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as rs1161178069, COSV57355123; called by muse, mutect2, varscan2
- MYH7 | c.4984C>A p.R1662S | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.417); catalogued as COSV100806206, COSV62520682; called by muse, mutect2, varscan2
- NECTIN3 | c.955G>T p.D319Y | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); catalogued as COSV100162501; called by muse, mutect2, varscan2
- NEDD1 | c.1219G>T p.G407C | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99901080; called by muse, mutect2, varscan2
- NLRP3 | c.211T>A p.W71R | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.56); PolyPhen benign (0.144); catalogued as COSV100276195; called by muse, mutect2
- NLRP9 | c.949G>A p.A317T | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.53); catalogued as COSV100243133; called by muse, mutect2, varscan2
- NMBR | c.416C>A p.A139D | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99237315; called by muse, mutect2
- NOTCH3 | c.1207G>A p.E403K | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1484483311, COSV54627113; called by muse, mutect2, varscan2
- NUB1 | c.439C>G p.Q147E | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.321); catalogued as COSV63426719; called by muse, mutect2, varscan2
- NUP107 | c.969+1G>T p.X323_splice | Splice Site (SNP) | VAF 12/80 reads (15%) | catalogued as CS1510927, COSV99971825; called by muse, varscan2
- OBSCN | c.7148G>T p.R2383L | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.813); catalogued as COSV99479881; called by muse, mutect2, varscan2
- OBSCN | c.13798G>T p.G4600C | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99479883; called by muse, mutect2, varscan2
- OCLN | c.1515C>A p.S505R | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as COSV100783829; called by muse, mutect2, varscan2
- OR2C3 | c.56C>A p.S19Y | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); catalogued as COSV100825720; called by muse, mutect2, varscan2
- OR2T2 | c.427T>G p.L143V | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.103); catalogued as COSV100737688; called by muse, mutect2, varscan2
- OR2T6 | c.841C>A p.L281I | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.116); catalogued as COSV100861574; called by muse, mutect2
- OR4K1 | c.677G>T p.R226L | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.023); catalogued as COSV53459544, COSV99579075; called by muse, mutect2, varscan2
- OR5H14 | c.211G>C p.A71P | Missense Mutation (SNP) | VAF 70/332 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV101454208; called by muse, varscan2
- PAK4 | c.100G>T p.G34W | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100426529; called by muse, mutect2, varscan2
- PAN3 | c.2524C>A p.L842I | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); catalogued as COSV99144882; called by muse, mutect2, varscan2
- PARP8 | c.2000C>T p.P667L | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV99891758; called by muse, mutect2, varscan2
- PCDHGA9 | c.734G>C p.R245P | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV53957174, COSV99539968; called by muse, mutect2, varscan2
- PDE10A | c.1654G>C p.E552Q | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100605190; called by muse, mutect2, varscan2
- PGLYRP1 | c.375G>A p.M125I | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99151508; called by muse, mutect2, varscan2
- PIP5K1B | c.646A>G p.K216E | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.173); catalogued as COSV99599057; called by muse, mutect2, varscan2
- PNPLA6 | c.1232C>T p.S411L (on ENST00000414982 / NM_001166111.2; = p.S363L on NM_006702.5) | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs372193709; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRKDC | c.7109G>C p.S2370T | Missense Mutation (SNP) | VAF 28/148 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs1337092489, COSV100041035; called by muse, mutect2, varscan2
- PRUNE1 | c.964C>G p.P322A | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as COSV54846395, COSV54847763; called by muse, mutect2, varscan2
- PZP | c.3899A>G p.N1300S | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs760841953, COSV99738241; called by muse, mutect2, varscan2
- RBMX2 | c.560C>T p.S187L | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.033); catalogued as rs371928616, COSV59728556; called by muse, mutect2, varscan2
- RIT2 | c.356A>T p.Q119L | Missense Mutation (SNP) | VAF 48/221 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.083); catalogued as COSV99950387; called by muse, mutect2, varscan2
- RND1 | c.185A>T p.E62V | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV100552181; called by muse, mutect2, varscan2
- SAGE1 | c.1753G>T p.E585* | Nonsense Mutation (SNP) | VAF 34/140 reads (24%) | catalogued as COSV100187459, COSV61017433; called by muse, mutect2, varscan2
- SAMD9L | c.4007G>A p.R1336K | Missense Mutation (SNP) | VAF 8/204 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV100560805, COSV59081164; called by muse, mutect2
- SATB1 | c.516-2A>C p.X172_splice | Splice Site (SNP) | VAF 6/42 reads (14%) | catalogued as COSV100113248; called by muse, mutect2, varscan2
- SCTR | c.452G>T p.S151I | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.42); catalogued as COSV99191545; called by muse, mutect2, varscan2
- SERPINA10 | c.131C>T p.A44V | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs781316392, COSV56228897; called by muse, mutect2, varscan2
- SGIP1 | c.314G>T p.S105I | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as COSV99391804; called by muse, mutect2, varscan2
- SLC17A1 | c.178T>G p.S60A | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.893); catalogued as COSV99765841; called by muse, mutect2
- SLC5A4 | c.1361A>C p.H454P | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.425); catalogued as COSV99831963; called by muse, mutect2
- SLC9A4 | c.1429T>C p.Y477H | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV99763213; called by muse, mutect2, varscan2
- SLFN11 | c.1327A>G p.R443G | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as COSV100390699; called by muse, mutect2, varscan2
- SLITRK5 | c.2042C>T p.A681V | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1256798513, COSV100280854; called by muse, mutect2, varscan2
- SMARCA1 | c.109G>T p.E37* | Nonsense Mutation (SNP) | VAF 19/107 reads (18%) | catalogued as COSV100946578; called by muse, mutect2, varscan2
- SOX5 | c.1217G>C p.G406A | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.51); PolyPhen benign (0.006); catalogued as COSV100507150; called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.2811G>T p.L937F | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.174); catalogued as COSV100561931; called by muse, mutect2, varscan2
- STXBP5L | c.262G>T p.G88W | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56524803; called by muse, mutect2
- SYNE3 | c.2596G>T p.G866W | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.909); catalogued as COSV100515596, COSV100516108; called by muse, mutect2, varscan2
- SYTL2 | c.874A>T p.N292Y | Missense Mutation (SNP) | VAF 8/153 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.429); catalogued as COSV100314396; called by muse, mutect2
- TAB3 | c.512C>T p.A171V | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs982923042, COSV99916333; called by muse, mutect2, varscan2
- TAGAP | c.1841C>T p.T614I | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.066); catalogued as rs369625327, COSV100487418; called by muse, mutect2, varscan2
- TC2N | c.1096A>G p.S366G | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV100562950; called by muse, mutect2, varscan2
- TCL1B | c.254C>G p.P85R | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100525790; called by muse, mutect2, varscan2
- TEDDM1 | c.130G>A p.V44M | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.526); catalogued as COSV100842957; called by muse, mutect2, varscan2
- TENM1 | c.686C>A p.P229Q | Missense Mutation (SNP) | VAF 32/186 reads (17%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.038); catalogued as COSV100950256; called by muse, mutect2, varscan2
- TENM3 | c.3935G>T p.G1312V | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.109); catalogued as COSV101305179; called by muse, mutect2, varscan2
- TEPP | c.244A>G p.M82V | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99333075; called by mutect2, varscan2
- TG | c.3996G>T p.Q1332H | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as rs748883405, COSV99601378; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TGIF2LX | c.319C>A p.R107S | Missense Mutation (SNP) | VAF 25/150 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.973); catalogued as COSV52215080, COSV52215374, COSV99383415; called by muse, mutect2, varscan2
- THSD7A | c.4945T>A p.L1649I | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV101349183; called by muse, mutect2, varscan2
- TIAM2 | c.2914G>C p.A972P | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.466); catalogued as COSV100019308; called by muse, mutect2, varscan2
- TJP1 | c.2226G>C p.R742S | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100632783; called by muse, mutect2, varscan2
- TLE4 | c.1477G>T p.V493L | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); catalogued as COSV54642295, COSV99513399; called by muse, mutect2, varscan2
- TMEFF1 | c.982A>T p.T328S | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.306); catalogued as COSV100614759; called by muse, mutect2, varscan2
- TP53TG5 | c.122C>T p.T41M | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs760512977, COSV65577993; called by muse, mutect2, varscan2
- TTLL1 | c.75G>T p.W25C | Missense Mutation (SNP) | VAF 25/177 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99840405; called by muse, mutect2, varscan2
- TTN | c.24401A>G p.E8134G (on ENST00000591111; = p.E7207G on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/57 reads (14%) | PolyPhen possibly damaging (0.653); catalogued as COSV100617133; called by muse, mutect2, varscan2
- TXNDC16 | c.1027A>G p.I343V | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV99909291; called by muse, mutect2, varscan2
- UBE2O | c.1051G>A p.E351K | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV100084687; called by muse, mutect2
- UROC1 | c.1373C>G p.P458R | Missense Mutation (SNP) | VAF 44/176 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.16); catalogued as COSV52032391; called by muse, mutect2, varscan2
- USP31 | c.1063A>G p.M355V | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs751426531, COSV54855296; called by muse, mutect2, varscan2
- USP34 | c.5282T>A p.L1761* | Nonsense Mutation (SNP) | VAF 6/33 reads (18%) | catalogued as COSV101277067; called by muse, mutect2, varscan2
- UTP14A | c.578A>G p.H193R | Missense Mutation (SNP) | VAF 30/146 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.034); catalogued as COSV100928970; called by muse, mutect2, varscan2
- VCAN | c.2938A>T p.K980* | Nonsense Mutation (SNP) | VAF 13/99 reads (13%) | catalogued as COSV99426150; called by muse, mutect2, varscan2
- XIAP | c.586G>T p.D196Y | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100848885; called by muse, mutect2, varscan2
- YY2 | c.235C>T p.L79F | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV100810778; called by muse, mutect2, varscan2
- ZNF331 | c.345A>C p.E115D | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV99467456; called by muse, mutect2, varscan2
- ZNF354A | c.1043A>G p.H348R | Missense Mutation (SNP) | VAF 18/136 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as COSV100234530; called by muse, mutect2, varscan2
- ZNF763 | c.872A>T p.K291I (on ENST00000358987 / NM_001367172.2; = p.K294I on NM_001012753.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100676141; called by muse, mutect2, varscan2
- CYB5R1 | c.714_715del p.K238Nfs*34 | Frame Shift Del (DEL) | VAF 11/77 reads (14%) | called by mutect2, pindel, varscan2
- D2HGDH | c.1142dup p.M381Ifs*37 | Frame Shift Ins (INS) | VAF 12/68 reads (18%) | called by mutect2, pindel, varscan2
- EN1 | c.1177T>C p.*393Qext*52 | Nonstop Mutation (SNP) | VAF 5/32 reads (16%) | called by muse, mutect2
- HDLBP | c.3479_3484del p.D1160_R1162delinsG | In Frame Del (DEL) | VAF 6/42 reads (14%) | called by mutect2, pindel, varscan2
- MPP5 | c.1579_1580del p.D527Lfs*20 | Frame Shift Del (DEL) | VAF 10/85 reads (12%) | called by pindel, varscan2
- PIAS2 | c.708del p.K237Sfs*25 | Frame Shift Del (DEL) | VAF 27/145 reads (19%) | called by mutect2, pindel, varscan2
- PRSS16 | c.178G>T p.G60W | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- TXNDC11 | c.1088del p.G363Afs*6 (on ENST00000356957 / NM_001303447.2; = p.G336Afs*6 on NM_015914.7 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 9/63 reads (14%) | called by mutect2, pindel, varscan2
- AASDH | c.2484G>T p.V828= | Silent (SNP) | VAF 12/71 reads (17%) | catalogued as COSV99221399; called by muse, mutect2, varscan2
- ABCC12 | c.591G>C p.A197= | Silent (SNP) | VAF 17/108 reads (16%) | catalogued as COSV100252796; called by muse, mutect2, varscan2
- ABHD1 | c.1170G>A p.G390= | Silent (SNP) | VAF 18/103 reads (17%) | catalogued as COSV99574558; called by mutect2, varscan2
- ADA2 | c.480C>T p.S160= | Silent (SNP) | VAF 8/88 reads (9%) | catalogued as COSV99376130; called by muse, mutect2
- AHNAK | c.17562C>T p.S5854= | Silent (SNP) | VAF 21/146 reads (14%) | catalogued as rs1179737677, COSV99947902; called by muse, mutect2, varscan2
- APBA2 | c.1074A>G p.P358= | Silent (SNP) | VAF 10/59 reads (17%) | catalogued as COSV101258180; called by muse, mutect2, varscan2
- ARSL | c.246C>A p.A82= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as COSV101140603; called by muse, mutect2, varscan2
- BRWD3 | c.5352A>G p.R1784= | Silent (SNP) | VAF 14/64 reads (22%) | catalogued as COSV100956172; called by muse, mutect2, varscan2
- CDC42EP1 | c.63G>T p.V21= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as COSV99312544; called by muse, mutect2
- CDH20 | c.12T>C p.S4= | Silent (SNP) | VAF 12/95 reads (13%) | catalogued as COSV53015166, COSV99405641; called by muse, mutect2, varscan2
- CDHR2 | c.1092C>T p.T364= | Silent (SNP) | VAF 16/42 reads (38%) | catalogued as COSV99991724; called by muse, mutect2, varscan2
- DAB2 | c.453C>T p.T151= | Silent (SNP) | VAF 15/68 reads (22%) | catalogued as rs373659542; called by muse, mutect2, varscan2
- DDX46 | c.1860A>C p.G620= | Silent (SNP) | VAF 7/75 reads (9%) | catalogued as COSV100844889; called by muse, mutect2
- DNAJC13 | c.1335C>T p.F445= | Silent (SNP) | VAF 8/73 reads (11%) | catalogued as COSV99607427; called by muse, mutect2, varscan2
- DNAJC22 | c.114G>T p.L38= | Silent (SNP) | VAF 13/98 reads (13%) | catalogued as COSV101222550; called by muse, mutect2, varscan2
- DPP10 | c.1252C>T p.L418= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as COSV100059040, COSV100067167; called by muse, mutect2, varscan2
- EAPP | c.69G>A p.L23= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as COSV99164240; called by muse, mutect2, varscan2
- EFL1 | c.1299C>T p.L433= | Silent (SNP) | VAF 33/185 reads (18%) | catalogued as COSV99187317; called by muse, mutect2, varscan2
- ENOX2 | c.123C>T p.A41= (on ENST00000338144 / NM_001382520.1; = p.A12= on NM_006375.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 21/90 reads (23%) | catalogued as COSV100584244; called by muse, mutect2, varscan2
- ESRRG | c.150G>C p.T50= | Silent (SNP) | VAF 8/59 reads (14%) | catalogued as COSV100753164, COSV63170713; called by muse, mutect2, varscan2
- EXT1 | c.93G>A p.S31= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV100984027; called by muse, mutect2
- FAT1 | c.12900G>T p.A4300= | Silent (SNP) | VAF 9/56 reads (16%) | catalogued as COSV101499399; called by muse, mutect2, varscan2
- FCRL1 | c.852C>A p.A284= | Silent (SNP) | VAF 12/69 reads (17%) | catalogued as COSV100839814; called by muse, mutect2, varscan2
- GATAD2A | c.639G>A p.R213= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as rs1314151346, COSV99390294; called by muse, mutect2, varscan2
- GRIK2 | c.2262G>A p.Q754= | Silent (SNP) | VAF 19/179 reads (11%) | catalogued as COSV100026869; called by muse, mutect2, varscan2
- GRM3 | c.921G>A p.E307= | Silent (SNP) | VAF 4/50 reads (8%) | catalogued as rs1467328655, COSV100862601; called by muse, mutect2
- HERC2 | c.7449T>C p.T2483= | Silent (SNP) | VAF 6/68 reads (9%) | catalogued as rs765941577, COSV99874436; called by muse, mutect2
- HIVEP2 | c.6804G>A p.G2268= | Silent (SNP) | VAF 6/77 reads (8%) | catalogued as COSV99173812; called by muse, mutect2
- IL10RA | c.1260G>T p.S420= | Silent (SNP) | VAF 14/51 reads (27%) | catalogued as COSV57141657; called by muse, mutect2, varscan2
- IMPA1 | c.228G>T p.G76= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as COSV99808977; called by muse, mutect2, varscan2
- INTS1 | c.579C>T p.S193= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as COSV101247987; called by muse, mutect2, varscan2
- IRS1 | c.1134G>T p.P378= | Silent (SNP) | VAF 22/90 reads (24%) | catalogued as COSV100524630; called by muse, mutect2, varscan2
- LAMA4 | c.4407C>T p.A1469= (on ENST00000230538 / NM_001105206.3; = p.A1462= on NM_002290.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/74 reads (8%) | called by muse, mutect2
- MAGIX | c.384G>A p.L128= | Silent (SNP) | VAF 23/109 reads (21%) | catalogued as COSV100891889; called by muse, mutect2, varscan2
- MROH5 | c.2391G>A p.K797= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as rs1398942793, COSV101436015; called by muse, mutect2, varscan2
- MTCH2 | c.420C>T p.P140= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV100207017; called by muse, mutect2, varscan2
- MTMR8 | c.1767C>A p.S589= | Silent (SNP) | VAF 13/69 reads (19%) | catalogued as COSV100878458; called by muse, mutect2, varscan2
- MTUS1 | c.1764G>T p.V588= | Silent (SNP) | VAF 43/166 reads (26%) | catalogued as COSV100029551; called by muse, mutect2, varscan2
- MYH3 | c.4327C>T p.L1443= | Silent (SNP) | VAF 11/59 reads (19%) | catalogued as COSV99878336; called by muse, mutect2, varscan2
- NEB | c.10512T>C p.D3504= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as COSV99424178; called by muse, mutect2, varscan2
- NIBAN1 | c.2133G>T p.A711= | Silent (SNP) | VAF 20/125 reads (16%) | catalogued as COSV100836416, COSV62284518; called by muse, mutect2, varscan2
- NLGN2 | c.328C>T p.L110= | Silent (SNP) | VAF 8/11 reads (73%) | catalogued as rs561309225, COSV100192826, COSV56657934; called by muse, varscan2
- NLRP3 | c.1767C>T p.Y589= | Silent (SNP) | VAF 16/74 reads (22%) | catalogued as COSV100276198, COSV99053282; called by muse, mutect2, varscan2
- OR4M1 | c.186G>T p.L62= | Silent (SNP) | VAF 84/309 reads (27%) | catalogued as COSV100271260; called by muse, mutect2, varscan2
- PCDHGA2 | c.1446C>T p.N482= | Silent (SNP) | VAF 13/118 reads (11%) | catalogued as rs745593461, COSV53957199; called by muse, mutect2, varscan2
- PDILT | c.1269G>C p.L423= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as rs1214957634, COSV100199501; called by muse, mutect2, varscan2
- PLEC | c.4653G>A p.Q1551= (on ENST00000322810 / NM_201380.4; = p.Q1441= on NM_000445.5) | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as COSV100515236; called by muse, mutect2
- PPP1R3C | c.780A>G p.Q260= | Silent (SNP) | VAF 26/85 reads (31%) | catalogued as rs753730318, COSV99490999; called by muse, mutect2, varscan2
- PTGFR | c.36T>A p.P12= | Silent (SNP) | VAF 16/85 reads (19%) | catalogued as COSV100882311; called by muse, mutect2, varscan2
- RERGL | c.462A>T p.A154= | Silent (SNP) | VAF 14/76 reads (18%) | catalogued as COSV99967950; called by muse, mutect2, varscan2
- RFT1 | c.81C>T p.I27= | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as rs781076485, COSV99965479; called by muse, mutect2, varscan2
- RPGRIP1L | c.2322C>T p.P774= | Silent (SNP) | VAF 23/100 reads (23%) | catalogued as COSV100046428; called by muse, mutect2, varscan2
- SLC12A3 | c.1422C>A p.V474= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as COSV99344317; called by mutect2, varscan2
- ST8SIA6 | c.948G>T p.V316= | Silent (SNP) | VAF 34/165 reads (21%) | catalogued as COSV101112153; called by muse, mutect2, varscan2
- STAB2 | c.4422C>A p.A1474= | Silent (SNP) | VAF 15/152 reads (10%) | catalogued as COSV101186045; called by muse, mutect2, varscan2
- STT3A | c.816G>A p.G272= | Silent (SNP) | VAF 13/141 reads (9%) | catalogued as COSV101205208; called by muse, mutect2
- THBS4 | c.2298T>C p.D766= | Silent (SNP) | VAF 14/70 reads (20%) | catalogued as COSV100644315; called by muse, mutect2, varscan2
- THEG | c.840C>T p.L280= | Silent (SNP) | VAF 21/114 reads (18%) | catalogued as COSV100700622, COSV61073541; called by muse, mutect2, varscan2
- TMEM174 | c.180C>A p.I60= | Silent (SNP) | VAF 20/149 reads (13%) | catalogued as COSV99703783; called by muse, mutect2, varscan2
- TSPEAR | c.1395C>T p.F465= | Silent (SNP) | VAF 13/132 reads (10%) | catalogued as rs782576857, COSV57869674; called by muse, mutect2, varscan2
- UGT2A2 | c.681G>T p.L227= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as COSV54141934, COSV99684458; called by muse, mutect2, varscan2
- YY1 | c.204C>A p.A68= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV99216861; called by muse, varscan2
- ZDHHC15 | c.540C>T p.Y180= | Silent (SNP) | VAF 17/80 reads (21%) | catalogued as COSV100973798; called by muse, mutect2, varscan2
- ZNF710 | c.1740C>T p.C580= | Silent (SNP) | VAF 28/59 reads (47%) | catalogued as rs564229454, COSV99184166; called by muse, mutect2, varscan2
- ZNF99 | c.2349T>C p.H783= | Silent (SNP) | VAF 17/82 reads (21%) | catalogued as rs1221353983, COSV101233849; called by muse, mutect2, varscan2
- AL132655.6 | chr20:58840368 C>G | 5'Flank (SNP) | VAF 17/86 reads (20%) | catalogued as COSV100006753; called by muse, mutect2, varscan2
- IGHM | c.1300+36T>C | Intron (SNP) | VAF 12/71 reads (17%) | called by muse, mutect2, varscan2
- JADE3 | c.-2G>T | 5'UTR (SNP) | VAF 4/40 reads (10%) | catalogued as COSV99509943; called by muse, mutect2, varscan2
- MAGED1 | c.46-318C>T | Intron (SNP) | VAF 7/43 reads (16%) | catalogued as rs782755455, COSV100431637; called by muse, mutect2, varscan2
- PHKG2 | c.*377G>T | 3'UTR (SNP) | VAF 37/238 reads (16%) | catalogued as COSV100079617; called by muse, mutect2, varscan2
- PRR12 | chr19:49594716 C>A | 5'Flank (SNP) | VAF 13/40 reads (33%) | catalogued as COSV99882459; called by muse, mutect2, varscan2
- RNU6-104P | chr8:43302005 C>G | 5'Flank (SNP) | VAF 15/103 reads (15%) | called by muse, mutect2, varscan2
